Somatic mutation profile of tumor specimen TCGA-CR-7370-01A (aliquot TCGA-CR-7370-01A-11D-2129-08) from TCGA case TCGA-CR-7370, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 72.5 years (26,468 days).
Specimen TCGA-CR-7370-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae894f32-4208-4af1-842a-79ddf8c416cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7370-10A (Blood Derived Normal), aliquot TCGA-CR-7370-10A-01D-2129-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72b4e07a-e93c-427e-830b-1b2dc9bbaf96

The open-access MAF lists 597 somatic variants for this specimen: 420 protein-altering or splice-affecting, 159 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 365, Silent 159, Nonsense Mutation 26, Frame Shift Del 17, Intron 8, Splice Site 6, RNA 6, Splice Region 4, 3'UTR 3, Frame Shift Ins 1, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.323A>T p.D108V | Missense Mutation (SNP) | VAF 23/27 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1339792331, COSV58682804, COSV58699096, COSV58719034; called by muse, mutect2, varscan2
- TP53 | c.1101-1G>A p.X367_splice | Splice Site (SNP) | VAF 54/145 reads (37%) | catalogued as rs876658982, COSV53196286; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- TP53 | c.712T>A p.C238S | Missense Mutation (SNP) | VAF 25/86 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519981, CM025271, CM056070, COSV52699956, COSV52707471, COSV52711035, COSV52711932; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.74T>A p.L25Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.212); catalogued as COSV99367843; called by muse, mutect2, varscan2
- ABCB1 | c.2153C>A p.A718D | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55945151, COSV99713028; called by muse, mutect2, varscan2
- ABI3BP | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as rs1268229335, COSV99426743; called by muse, mutect2, varscan2
- ACHE | c.1064T>C p.L355P | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99574069; called by muse, mutect2, varscan2
- ACKR1 | c.701C>A p.A234E | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.594); catalogued as COSV100929557; called by muse, mutect2, varscan2
- ACOT9 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs754131492, COSV100321273; called by muse, mutect2, varscan2
- ADAMTS7 | c.2839G>T p.A947S | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.217); catalogued as COSV101183100; called by muse, mutect2, varscan2
- ADRA1A | c.495G>C p.W165C | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs997765683, COSV99370915; called by muse, mutect2, varscan2
- AHNAK2 | c.1805G>T p.R602I | Missense Mutation (SNP) | VAF 54/640 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV100317475; called by muse, mutect2
- AKAP3 | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV57416871, COSV99962121; called by muse, mutect2, varscan2
- AKAP4 | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 57/104 reads (55%) | catalogued as COSV100654259; called by muse, mutect2, varscan2
- AL592490.1 | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 89/121 reads (74%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs755876195, COSV101308192; called by muse, mutect2, varscan2
- ALX1 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV100374404, COSV57494158; called by muse, mutect2, varscan2
- AMER1 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV100366089; called by muse, mutect2, varscan2
- ANK2 | c.2738C>T p.A913V | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV100001592; called by muse, mutect2, varscan2
- ANK2 | c.5786C>T p.S1929L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs779278730, COSV52173219, COSV52192251; called by muse, mutect2, varscan2
- ANKRD24 | c.1780G>T p.A594S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); catalogued as rs1352898018, COSV99517481; called by muse, mutect2
- ANKRD50 | c.2588G>A p.C863Y | Missense Mutation (SNP) | VAF 70/103 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101538954; called by muse, mutect2, varscan2
- ANO5 | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV100201839; called by muse, mutect2, varscan2
- AP3B1 | c.2536C>A p.L846I | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99671329; called by muse, mutect2, varscan2
- ARHGAP36 | c.1318G>T p.V440L | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (1); PolyPhen possibly damaging (0.654); catalogued as rs1191757469, COSV52266034, COSV52269379; called by muse, mutect2, varscan2
- ARMC3 | c.297T>A p.D99E | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0.316); catalogued as COSV99958054; called by muse, mutect2, varscan2
- ARPP21 | c.1544G>A p.G515E | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV99492030; called by muse, mutect2, varscan2
- ASIC2 | c.1532C>A p.A511D | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV99860087; called by muse, mutect2, varscan2
- ATP10B | c.3034G>T p.E1012* | Nonsense Mutation (SNP) | VAF 52/97 reads (54%) | catalogued as COSV100514932, COSV59148006; called by muse, mutect2, varscan2
- ATP13A5 | c.1552G>T p.G518C | Missense Mutation (SNP) | VAF 34/324 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100665130; called by muse, mutect2, varscan2
- ATRX | c.1597G>C p.E533Q | Missense Mutation (SNP) | VAF 170/301 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV100970751, COSV64877534; called by muse, mutect2, varscan2
- BAZ2B | c.2884C>T p.Q962* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as COSV99680963; called by muse, mutect2, varscan2
- BEST3 | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99876207; called by muse, mutect2, varscan2
- BHLHE22 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.733); catalogued as COSV100417747; called by muse, mutect2, varscan2
- BMP2 | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758959332, COSV66577642; called by muse, mutect2, varscan2
- BMX | c.787C>G p.Q263E | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV100564459; called by muse, mutect2, varscan2
- BPIFC | c.1007C>A p.P336H | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100301041; called by muse, mutect2, varscan2
- BRINP2 | c.556A>T p.S186C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100838075; called by muse, mutect2, varscan2
- BRS3 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as COSV101036567; called by muse, mutect2, varscan2
- BSN | c.3373G>C p.E1125Q | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776182411, COSV99608408; called by muse, mutect2, varscan2
- C11orf16 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV100393725; called by muse, mutect2, varscan2
- C12orf50 | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 28/64 reads (44%) | catalogued as rs762391760, COSV100072233; called by muse, mutect2, varscan2
- C1R | c.1655G>T p.R552L (on ENST00000536053 / NM_001354346.2; = p.R538L on NM_001733.7) | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as COSV101605620; called by muse, mutect2, varscan2
- C3orf20 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 48/75 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV99513926; called by muse, mutect2, varscan2
- CA6 | c.464C>A p.A155E | Missense Mutation (SNP) | VAF 111/170 reads (65%) | SIFT tolerated (0.26); PolyPhen benign (0.094); catalogued as COSV66261580, COSV66263237; called by muse, mutect2, varscan2
- CACNA1G | c.3344G>T p.R1115L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV100661787, COSV100662963; called by muse, varscan2
- CALB1 | c.311T>A p.M104K | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as COSV99618239; called by muse, mutect2, varscan2
- CCDC126 | c.240G>T p.A80= | Splice Region (SNP) | VAF 26/64 reads (41%) | catalogued as COSV100277962, COSV56739828; called by muse, mutect2, varscan2
- CCDC189 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV100079581; called by muse, mutect2, varscan2
- CCDC8 | c.1464G>A p.W488* | Nonsense Mutation (SNP) | VAF 37/99 reads (37%) | catalogued as COSV100282021; called by muse, mutect2, varscan2
- CCL1 | c.38T>A p.L13Q | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99861735; called by muse, mutect2, varscan2
- CD1E | c.833G>C p.G278A | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.174); catalogued as COSV100936999; called by muse, mutect2, varscan2
- CDKL5 | c.1445A>G p.Y482C | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); catalogued as COSV101184306; called by muse, mutect2, varscan2
- CEACAM7 | c.632T>A p.I211K | Missense Mutation (SNP) | VAF 100/238 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99137219; called by muse, mutect2, varscan2
- CEP104 | c.2397G>T p.L799F | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100986617; called by muse, mutect2, varscan2
- CFAP44 | c.1928A>G p.Y643C | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.785); catalogued as rs199927736, COSV99869506; called by muse, mutect2, varscan2
- CFAP47 | c.5159G>T p.C1720F | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100545332; called by muse, mutect2, varscan2
- CHAT | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs769204680, COSV60333235; called by muse, mutect2, varscan2
- CHD1L | c.1483G>C p.E495Q | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as rs962246846, COSV100787442; called by muse, mutect2
- CHD3 | c.5846A>G p.N1949S (on ENST00000330494 / NM_001005273.3; = p.N1915S on NM_005852.4) | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.956); catalogued as rs757766809, COSV100177199; called by muse, mutect2, varscan2
- CHFR | c.1256C>G p.S419* (on ENST00000432561 / NM_001161345.1; = p.S378* on NM_018223.2) | Nonsense Mutation (SNP) | VAF 32/141 reads (23%) | catalogued as COSV99905293; called by muse, mutect2, varscan2
- CHML | c.796C>G p.L266V | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100087402, COSV59365995; called by muse, mutect2, varscan2
- CIT | c.2987G>T p.R996L | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99949566; called by muse, mutect2, varscan2
- CNTN4 | c.2381T>G p.V794G | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV100639242; called by muse, mutect2, varscan2
- CNTNAP1 | c.3271A>T p.S1091C | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.421); catalogued as COSV99226372; called by muse, mutect2, varscan2
- COG5 | c.96G>A p.G32= | Splice Region (SNP) | VAF 11/50 reads (22%) | catalogued as rs1161117992, CD1211719, COSV99772106; called by muse, mutect2, varscan2
- COL11A1 | c.2197-1G>A p.X733_splice | Splice Site (SNP) | VAF 110/167 reads (66%) | catalogued as COSV100616486; called by muse, mutect2, varscan2
- COL11A1 | c.1292C>A p.P431Q | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs778541934, COSV100616488; called by muse, mutect2, varscan2
- COL11A2 | c.1612-1G>T p.X538_splice (on ENST00000341947 / NM_080680.3; = p.X431_splice on NM_080679.2) | Splice Site (SNP) | VAF 16/28 reads (57%) | catalogued as COSV100553989; called by muse, mutect2, varscan2
- COL15A1 | c.700C>A p.L234M | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.053); catalogued as COSV66645911; called by muse, mutect2, varscan2
- COL22A1 | c.4642G>A p.G1548S | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100278423; called by muse, mutect2
- COL5A2 | c.2428G>T p.G810C | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100880307; called by muse, mutect2, varscan2
- COL6A2 | c.2179G>T p.A727S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100153516; called by muse, mutect2, varscan2
- COL8A1 | c.596C>A p.P199Q | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); catalogued as COSV99657725; called by muse, mutect2, varscan2
- CRB1 | c.3361C>A p.Q1121K | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100957868; called by muse, mutect2, varscan2
- CSMD1 | c.2836G>T p.G946W (on ENST00000520002; = p.G945W on NM_033225.6) | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59320036; called by muse, mutect2, varscan2
- CSMD2 | c.4246G>A p.A1416T | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs375435304; called by muse, mutect2, varscan2
- CUL7 | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99538564; called by muse, mutect2, varscan2
- CWH43 | c.800C>T p.T267I | Missense Mutation (SNP) | VAF 52/74 reads (70%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV99893401; called by muse, mutect2, varscan2
- CXorf38 | c.382C>A p.Q128K | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100010373; called by muse, mutect2, varscan2
- CYP46A1 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 89/225 reads (40%) | catalogued as COSV55893450, COSV55894536; called by muse, mutect2, varscan2
- DCC | c.2305G>A p.A769T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as rs754564228, COSV100499984; called by muse, mutect2
- DCST2 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as COSV99791910; called by muse, mutect2, varscan2
- DDIT4L | c.64G>T p.G22C | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.161); catalogued as COSV56767831; called by muse, mutect2, varscan2
- DDR2 | c.938G>T p.W313L | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100906556; called by muse, mutect2, varscan2
- DDX43 | c.895C>A p.P299T | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100946326, COSV64836667; called by muse, mutect2, varscan2
- DEDD | c.371G>C p.R124P | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.29); catalogued as COSV100919088; called by muse, mutect2, varscan2
- DEGS2 | c.647C>G p.S216C | Missense Mutation (SNP) | VAF 88/105 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV59783712, COSV99979202; called by muse, mutect2, varscan2
- DNAH11 | c.6592C>T p.P2198S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV60968753; called by muse, mutect2, varscan2
- DNAH2 | c.2617C>G p.L873V | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV101209296; called by muse, mutect2, varscan2
- DNAH7 | c.2845A>G p.T949A | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100415180; called by muse, mutect2
- DNAI3 | c.1254C>G p.I418M | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV99641823; called by muse, mutect2, varscan2
- DNMT3A | c.2065A>T p.S689C | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV99262281; called by muse, mutect2, varscan2
- DPP10 | c.2217C>G p.I739M | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100064939; called by muse, mutect2, varscan2
- DSCAM | c.2967G>T p.Q989H | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.819); catalogued as COSV101260097, COSV101261408; called by muse, mutect2, varscan2
- ECEL1 | c.809T>A p.L270Q | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100458711; called by muse, mutect2, varscan2
- ECEL1 | c.808C>A p.L270M | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100458714; called by muse, mutect2, varscan2
- EEF2K | c.1281T>G p.D427E | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99533136; called by muse, mutect2, varscan2
- ENTHD1 | c.1238G>A p.G413E | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV100288741; called by muse, mutect2, varscan2
- EPB41L3 | c.2697G>T p.E899D | Missense Mutation (SNP) | VAF 197/253 reads (78%) | SIFT tolerated (0.19); PolyPhen benign (0.141); catalogued as COSV100548423; called by muse, mutect2, varscan2
- ERICH3 | c.1238G>T p.R413M | Missense Mutation (SNP) | VAF 55/92 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100444311; called by muse, mutect2, varscan2
- FAM135B | c.3950G>C p.R1317P | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99423835; called by muse, mutect2, varscan2
- FAM98C | c.944G>T p.R315L | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53039498, COSV99384885; called by muse, mutect2, varscan2
- FAM9B | c.325C>T p.L109F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.961); catalogued as COSV100510989; called by muse, mutect2, varscan2
- FASTKD3 | c.695G>A p.G232D | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as COSV99241690; called by muse, mutect2, varscan2
- FAT4 | c.6019G>T p.D2007Y | Missense Mutation (SNP) | VAF 79/132 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100628581; called by muse, mutect2, varscan2
- FBXO24 | c.927C>A p.N309K (on ENST00000241071 / NM_033506.3; = p.N347K on NM_012172.5) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.13); catalogued as COSV99575327; called by muse, mutect2
- FBXW10 | c.773T>C p.L258S | Missense Mutation (SNP) | VAF 59/263 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100111435, COSV57321048; called by muse, mutect2, varscan2
- FIGN | c.1531G>T p.A511S | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.832); catalogued as COSV100292340, COSV60763026; called by muse, mutect2, varscan2
- FLRT2 | c.173C>G p.P58R | Missense Mutation (SNP) | VAF 172/223 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100420384; called by muse, mutect2, varscan2
- FMN2 | c.2222C>T p.A741V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs777197512, COSV100144508; called by muse, mutect2, varscan2
- FOXB2 | c.289T>A p.F97I | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100942340; called by muse, mutect2, varscan2
- FREM2 | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99748713; called by muse, mutect2, varscan2
- FRMD1 | c.1492C>A p.P498T | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.85); PolyPhen benign (0.218); catalogued as COSV99349744; called by muse, mutect2, varscan2
- FRMD1 | c.715G>T p.G239C | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99349748; called by muse, mutect2, varscan2
- FUT9 | c.677T>A p.V226D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV100133597, COSV56146059; called by muse, mutect2, varscan2
- G6PC | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs1416734457, COSV99520827; called by muse, mutect2, varscan2
- GAGE10 | c.224G>C p.S75T | Missense Mutation (SNP) | VAF 72/238 reads (30%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.971); catalogued as COSV101339935, COSV101339989; called by muse, mutect2, varscan2
- GALNT15 | c.1337G>T p.G446V | Missense Mutation (SNP) | VAF 45/76 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV100327647; called by muse, mutect2, varscan2
- GBF1 | c.1273G>A p.E425K (on ENST00000369983 / NM_001377137.1; = p.E424K on NM_004193.3) | Missense Mutation (SNP) | VAF 196/288 reads (68%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as COSV100890479; called by muse, mutect2, varscan2
- GCAT | c.1204G>T p.D402Y | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99959780; called by muse, mutect2, varscan2
- GCC1 | c.265A>T p.T89S | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.071); catalogued as COSV99133742; called by muse, mutect2, varscan2
- GCOM1 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.127); catalogued as COSV99984931; called by muse, mutect2, varscan2
- GGN | c.1758C>A p.F586L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as rs1266090300, COSV99287465; called by muse, mutect2, varscan2
- GLI2 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.042); catalogued as COSV100083166; called by muse, mutect2, varscan2
- GLP2R | c.1550C>A p.P517H | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV99301990; called by muse, mutect2, varscan2
- GMPS | c.941A>G p.D314G | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs377527627; called by muse, mutect2
- GOLGA6A | c.976C>G p.Q326E | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.388); catalogued as COSV99297199; called by mutect2, varscan2
- GPR139 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746326530, COSV58503678; called by muse, mutect2, varscan2
- GPR6 | c.799G>T p.A267S | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as COSV99254322; called by muse, mutect2, varscan2
- GRID1 | c.1114-1G>T p.X372_splice | Splice Site (SNP) | VAF 24/35 reads (69%) | catalogued as COSV100024012; called by muse, mutect2, varscan2
- GRID2 | c.1761G>C p.L587F | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56224457, COSV99940798; called by muse, mutect2
- GTF2H3 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs571119521, COSV57458387; called by muse, mutect2, varscan2
- GYS1 | c.722G>T p.R241L | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs192597341, COSV99620743; called by muse, mutect2, varscan2
- HDAC6 | c.2236G>T p.G746W | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100490817; called by muse, mutect2, varscan2
- HDAC6 | c.2887G>C p.D963H | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100490820; called by muse, mutect2
- HEPACAM2 | c.218C>T p.P73L (on ENST00000394468 / NM_001039372.4; = p.P61L on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as COSV100506551; called by muse, mutect2, varscan2
- HFM1 | c.1283T>C p.V428A | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99645963; called by muse, mutect2, varscan2
- HK3 | c.166G>C p.G56R | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV99458501; called by muse, mutect2, varscan2
- HPCAL1 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as COSV100324004; called by muse, mutect2, varscan2
- HUWE1 | c.659C>G p.T220R | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.193); catalogued as COSV99472264; called by muse, mutect2, varscan2
- IFRD1 | c.350A>G p.E117G | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV99133913; called by muse, mutect2, varscan2
- IGKV1D-16 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 66/203 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as rs746286068; called by muse, mutect2, varscan2
- IGSF9B | c.2776C>A p.P926T | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100317605; called by muse, mutect2, varscan2
- IRF7 | c.1174G>A p.E392K (on ENST00000397566; = p.E379K on NM_001572.5) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV99200293; called by muse, mutect2, varscan2
- ISM2 | c.673G>T p.D225Y | Missense Mutation (SNP) | VAF 119/294 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99376635; called by muse, mutect2, varscan2
- ITPRID2 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100238244; called by muse, mutect2, varscan2
- KCNH1 | c.1070G>T p.R357L (on ENST00000271751 / NM_172362.3; = p.R330L on NM_002238.4) | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1511903, CM165939, COSV99659211; called by muse, mutect2, varscan2
- KCNJ12 | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs782612333, COSV100054817; called by muse, mutect2
- KCNT2 | c.2977C>A p.R993S | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.115); catalogued as rs1440122635, COSV54077893, COSV99655816; called by muse, mutect2, varscan2
- KIF12 | c.873C>G p.I291M (on ENST00000640217; = p.I153M on NM_138424.1) | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100936143; called by muse, mutect2, varscan2
- KMT2C | c.7226A>G p.Q2409R | Missense Mutation (SNP) | VAF 114/328 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs748975674, COSV100071744; called by muse, mutect2, varscan2
- KRT10 | c.1276G>C p.E426Q | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV54088905, COSV54090327, COSV99510056; called by muse, mutect2
- KRTAP5-9 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 102/272 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV101603631; called by muse, mutect2, varscan2
- L3HYPDH | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99711588; called by muse, mutect2
- L3HYPDH | c.294G>T p.E98D | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV54199827; called by muse, mutect2
- LAIR2 | c.186G>T p.R62S | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV100003278, COSV56623292; called by muse, mutect2, varscan2
- LAIR2 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 48/127 reads (38%) | catalogued as COSV100003279, COSV56623042; called by muse, mutect2, varscan2
- LAMA2 | c.4994G>T p.G1665V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.516); catalogued as COSV101370440, COSV70346025; called by muse, mutect2, varscan2
- LAMA5 | c.9505-1G>A p.X3169_splice | Splice Site (SNP) | VAF 22/45 reads (49%) | catalogued as COSV53362286, COSV99439932; called by muse, mutect2, varscan2
- LARP4B | c.1001A>T p.Q334L | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100295340; called by muse, mutect2, varscan2
- LCT | c.2938T>A p.W980R | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99929459; called by muse, mutect2, varscan2
- LILRB4 | c.815T>A p.L272H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99553811; called by muse, mutect2, varscan2
- LIMA1 | c.890A>G p.E297G | Missense Mutation (SNP) | VAF 116/242 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100372440; called by muse, mutect2, varscan2
- LIN28B | c.193C>G p.H65D | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100558809; called by muse, mutect2, varscan2
- LMLN | c.704G>A p.C235Y | Missense Mutation (SNP) | VAF 17/337 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100218558; called by muse, mutect2
- LRAT | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT tolerated (0.6); PolyPhen benign (0.017); catalogued as COSV60476778; called by muse, mutect2, varscan2
- LRFN2 | c.1342C>T p.R448W | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as rs1338608982, COSV100599388, COSV57824249; called by muse, mutect2, varscan2
- LTBP1 | c.726G>T p.W242C | Missense Mutation (SNP) | VAF 68/156 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.436); catalogued as COSV100617132; called by muse, mutect2, varscan2
- LYN | c.937G>T p.E313* | Nonsense Mutation (SNP) | VAF 16/81 reads (20%) | catalogued as COSV101319602; called by muse, mutect2, varscan2
- MAP1B | c.3070G>A p.D1024N | Missense Mutation (SNP) | VAF 38/50 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV99702364; called by muse, mutect2, varscan2
- MAP3K19 | c.2405C>T p.P802L | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59643191; called by muse, mutect2, varscan2
- MAPK8IP2 | c.191G>T p.R64L | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV99151227; called by muse, mutect2, varscan2
- MAT1A | c.509C>G p.S170C | Missense Mutation (SNP) | VAF 56/86 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV100944437, COSV64745131; called by muse, mutect2, varscan2
- MED12L | c.2893G>C p.V965L | Missense Mutation (SNP) | VAF 77/185 reads (42%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.494); catalogued as COSV99853082; called by muse, mutect2, varscan2
- MICAL3 | c.4515del p.R1506Efs*99 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | catalogued as rs1569078017; called by mutect2, pindel
- MINDY1 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV56497908; called by muse, mutect2
- MKRN3 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100091125; called by muse, mutect2, varscan2
- MROH2B | c.2106G>T p.M702I | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV68183558; called by muse, mutect2, varscan2
- MROH5 | c.1540G>C p.E514Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.779); catalogued as COSV101435990; called by muse, mutect2, varscan2
- MSN | c.1223G>T p.R408L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100814258, COSV64305600; called by muse, mutect2, varscan2
- MUC17 | c.4459G>A p.V1487I | Missense Mutation (SNP) | VAF 103/358 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs770202672, COSV100073170; called by muse, mutect2, varscan2
- MUC5AC | c.14377G>A p.A4793T | Missense Mutation (SNP) | VAF 117/322 reads (36%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.991); catalogued as COSV100611436; called by muse, mutect2, varscan2
- MYH10 | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV99345197; called by muse, mutect2, varscan2
- MYH13 | c.5608G>T p.D1870Y | Missense Mutation (SNP) | VAF 104/277 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52820233, COSV99353928; called by muse, mutect2, varscan2
- MYH3 | c.446A>T p.Q149L | Missense Mutation (SNP) | VAF 91/290 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV99878210; called by muse, mutect2, varscan2
- MYH4 | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 55/152 reads (36%) | catalogued as COSV99701247; called by muse, mutect2, varscan2
- MYH8 | c.2042C>T p.T681I | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.135); catalogued as COSV101238398; called by muse, mutect2, varscan2
- MYLK2 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101044781; called by muse, mutect2, varscan2
- MYO15A | c.3867-2A>G p.X1289_splice | Splice Site (SNP) | VAF 56/166 reads (34%) | catalogued as COSV99232736; called by muse, mutect2, varscan2
- MYO16 | c.5012C>A p.P1671H | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100696699; called by muse, mutect2
- NAV3 | c.4865A>C p.Q1622P | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV99890783; called by muse, mutect2, varscan2
- NBAS | c.5507A>T p.K1836M | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as COSV99869569; called by muse, mutect2, varscan2
- NBPF11 | c.614A>G p.E205G | Missense Mutation (SNP) | VAF 91/305 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1411774851; called by muse, mutect2, varscan2
- NCCRP1 | c.765G>C p.E255D | Missense Mutation (SNP) | VAF 139/369 reads (38%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.584); catalogued as COSV100355794; called by muse, mutect2, varscan2
- NCOA6 | c.2434G>T p.V812F | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.289); catalogued as COSV100750026; called by muse, mutect2, varscan2
- NCOA6 | c.1229G>T p.G410V | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as COSV100749958; called by muse, mutect2, varscan2
- NEURL3 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100182417; called by muse, mutect2, varscan2
- NIM1K | c.1289C>G p.S430C | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100390147; called by muse, mutect2, varscan2
- NLRP12 | c.3146C>A p.A1049E | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as COSV100145265; called by muse, mutect2, varscan2
- NOS1 | c.2764G>A p.G922R | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100500576; called by muse, mutect2, varscan2
- NOS2 | c.3420G>T p.R1140S | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100569654; called by muse, mutect2, varscan2
- NPAP1 | c.1287G>T p.L429F | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV100275361; called by muse, mutect2, varscan2
- NPTXR | c.1242C>G p.I414M | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60728470, COSV60729074; called by muse, mutect2, varscan2
- NR0B1 | c.862C>A p.R288S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CD128640, COSV100973523; called by muse, mutect2, varscan2
- NRG2 | c.1648C>A p.P550T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56831105, COSV99180205; called by muse, mutect2, varscan2
- NRXN2 | c.3345G>T p.W1115C | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99634086; called by muse, mutect2, varscan2
- NSMAF | c.225C>G p.I75M | Missense Mutation (SNP) | VAF 13/291 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99232848; called by muse, mutect2
- NUP54 | c.1252C>T p.Q418* | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | catalogued as COSV99345284; called by muse, mutect2, varscan2
- NXPE1 | c.983C>T p.T328I (on ENST00000424269; = p.T186I on NM_152315.5) | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs1264067269, COSV99320450; called by muse, mutect2, varscan2
- NXPE4 | c.641A>C p.Q214P | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV100970442; called by muse, mutect2, varscan2
- OLFM1 | c.707C>A p.P236H (on ENST00000371793 / NM_001282611.2; = p.P218H on NM_014279.5) | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV53283339, COSV99423809; called by muse, mutect2, varscan2
- OLIG3 | c.355C>G p.R119G | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100880270; called by muse, mutect2, varscan2
- OPALIN | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 62/106 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100959618; called by muse, mutect2, varscan2
- OR10A4 | c.769A>T p.I257F | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.53); catalogued as COSV101139514; called by muse, mutect2, varscan2
- OR2AT4 | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100532337; called by muse, mutect2, varscan2
- OR2B6 | c.266G>A p.R89K | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV104391639, COSV99773754; called by muse, mutect2, varscan2
- OR2G3 | c.897G>C p.E299D | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100180604; called by muse, mutect2, varscan2
- OR2M2 | c.388C>A p.L130I | Missense Mutation (SNP) | VAF 142/427 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100677225, COSV100677329, COSV62899446; called by muse, mutect2, varscan2
- OR2M7 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100522535; called by muse, mutect2, varscan2
- OR2T12 | c.780del p.K261Nfs*23 | Frame Shift Del (DEL) | VAF 50/140 reads (36%) | catalogued as COSV100527716; called by mutect2, pindel*, varscan2
- OR4P4 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 84/212 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs745457184, COSV100111725, COSV58923573; called by muse, mutect2, varscan2
- OR51B6 | c.277G>T p.G93* | Nonsense Mutation (SNP) | VAF 56/127 reads (44%) | catalogued as COSV100971275; called by muse, mutect2, varscan2
- OR52A5 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as rs267602939, COSV100263443; called by muse, mutect2, varscan2
- OR5B17 | c.145C>G p.L49V | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.049); catalogued as COSV100641900; called by muse, mutect2, varscan2
- OR5J2 | c.563C>A p.S188* | Nonsense Mutation (SNP) | VAF 49/128 reads (38%) | catalogued as COSV100399012; called by muse, mutect2, varscan2
- OR5W2 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.87); PolyPhen benign (0.152); catalogued as rs1158488444, COSV100747621, COSV60615213; called by muse, mutect2, varscan2
- OR8J1 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as COSV100274998, COSV100275285; called by muse, mutect2, varscan2
- OTOA | c.317T>A p.L106Q | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99624489; called by muse, mutect2, varscan2
- OTOGL | c.1900G>A p.G634S (on ENST00000547103; = p.G625S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101509245; called by muse, mutect2, varscan2
- OTOGL | c.1901G>T p.G634V (on ENST00000547103; = p.G625V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV72006969; called by muse, mutect2, varscan2
- P4HA2 | c.1366A>T p.N456Y | Missense Mutation (SNP) | VAF 38/51 reads (75%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.544); catalogued as COSV99387012; called by muse, mutect2, varscan2
- P4HA3 | c.435C>A p.D145E | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV100525717; called by muse, mutect2, varscan2
- PARD3 | c.1054A>G p.I352V | Missense Mutation (SNP) | VAF 75/131 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1385157485, COSV100400953; called by muse, varscan2
- PARP9 | c.49G>T p.G17C | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.419); catalogued as COSV100831145; called by muse, mutect2, varscan2
- PATJ | c.2911G>T p.D971Y | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100334173; called by muse, mutect2, varscan2
- PCDH11X | c.2052G>T p.L684F | Missense Mutation (SNP) | VAF 73/131 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.17); catalogued as COSV100011660; called by muse, mutect2, varscan2
- PCDH11X | c.2053G>T p.V685F | Missense Mutation (SNP) | VAF 74/132 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100011664; called by muse, mutect2, varscan2
- PCDH17 | c.3010G>C p.D1004H | Missense Mutation (SNP) | VAF 57/81 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100931632, COSV100932190, COSV64971705; called by muse, mutect2, varscan2
- PCDHA4 | c.1445C>A p.A482E | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV100793425, COSV63540934; called by muse, mutect2, varscan2
- PCDHGA1 | c.2195T>A p.L732* | Nonsense Mutation (SNP) | VAF 55/91 reads (60%) | catalogued as COSV100965993; called by muse, mutect2, varscan2
- PCDHGA12 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.053); catalogued as rs376827063; called by muse, mutect2, varscan2
- PCDHGB6 | c.1498G>T p.A500S | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV54020526, COSV99538082; called by muse, mutect2, varscan2
- PCSK9 | c.707G>A p.G236D | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100135197; called by muse, mutect2, varscan2
- PDE10A | c.2173G>T p.G725C | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100605068; called by muse, mutect2, varscan2
- PDE1C | c.1403C>G p.S468W | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV100372471, COSV58504631; called by muse, mutect2, varscan2
- PDHA2 | c.922G>A p.V308I | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV99756881; called by muse, mutect2, varscan2
- PEG3 | c.4590G>C p.M1530I | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99688874; called by muse, mutect2, varscan2
- PEX1 | c.1349G>C p.R450T | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV50397142; called by muse, mutect2, varscan2
- PIH1D2 | c.906C>G p.I302M | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.77); catalogued as COSV99734702; called by muse, mutect2, varscan2
- PIK3R2 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.305); catalogued as rs777991540, COSV99717407, COSV99717768; called by muse, mutect2, varscan2
- PITPNC1 | c.397A>T p.R133* | Nonsense Mutation (SNP) | VAF 27/64 reads (42%) | catalogued as COSV100083425; called by muse, mutect2, varscan2
- PKDREJ | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 133/279 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV53547023; called by muse, mutect2, varscan2
- PLCB1 | c.358G>T p.V120L | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV62038320, COSV62062829; called by muse, mutect2, varscan2
- PLCH1 | c.1719C>A p.D573E (on ENST00000340059 / NM_001130960.2; = p.D585E on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV100396825; called by muse, mutect2
- PLSCR4 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 16/32 reads (50%) | catalogued as rs765957176, COSV100724209; called by muse, mutect2, varscan2
- PPM1A | c.1048G>T p.E350* | Nonsense Mutation (SNP) | VAF 30/73 reads (41%) | catalogued as COSV100348884; called by muse, mutect2, varscan2
- PPP1R3A | c.2954C>A p.S985* | Nonsense Mutation (SNP) | VAF 12/106 reads (11%) | catalogued as COSV99492901, COSV99493950; called by muse, mutect2, varscan2
- PRDM9 | c.626A>G p.Q209R | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs1261168316, COSV99690443; called by muse, mutect2, varscan2
- PRMT3 | c.1117G>A p.V373M | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1223112233, COSV100423912; called by muse, mutect2, varscan2
- PROX1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV99799389; called by muse, mutect2, varscan2
- PROX1 | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as COSV99799391; called by muse, mutect2, varscan2
- PRR12 | c.3068G>T p.R1023M (on ENST00000615927; = p.R1844M on NM_020719.3) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101330665; called by muse, mutect2
- PRX | c.66G>C p.E22D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99397696; called by muse, mutect2
- PSMF1 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 233/499 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.745); catalogued as rs371970750, COSV55673396; called by muse, mutect2, varscan2
- PTGER4 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV100201553; called by muse, mutect2, varscan2
- PTK7 | c.1979G>T p.G660V | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100030165; called by muse, mutect2, varscan2
- PTPRM | c.428C>A p.A143E | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1202261398, COSV100157203; called by muse, mutect2
- PTPRM | c.1990G>T p.E664* | Nonsense Mutation (SNP) | VAF 134/173 reads (77%) | catalogued as COSV100157204; called by muse, mutect2, varscan2
- PXDN | c.3454C>A p.L1152M | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99413451; called by muse, mutect2, varscan2
- PXDN | c.2735C>T p.A912V | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99413452; called by muse, mutect2, varscan2
- PXDN | c.1318C>G p.Q440E | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as COSV99413454; called by muse, mutect2, varscan2
- RARG | c.123G>C p.M41I | Missense Mutation (SNP) | VAF 63/93 reads (68%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV100553460; called by muse, mutect2, varscan2
- RASGRP1 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV60366593; called by muse, mutect2, varscan2
- RB1 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 52/84 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.191); catalogued as COSV99031764, COSV99924725; called by muse, mutect2, varscan2
- RBFOX1 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1460472091, COSV101382395; called by muse, mutect2, varscan2
- RBM34 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.723); catalogued as COSV100783957; called by muse, mutect2, varscan2
- REG1A | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV99286795; called by muse, mutect2, varscan2
- RELB | c.1395C>A p.D465E | Missense Mutation (SNP) | VAF 44/262 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV99672900; called by muse, mutect2, varscan2
- RELN | c.623C>A p.S208Y | Missense Mutation (SNP) | VAF 68/149 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100633698, COSV59034182; called by muse, mutect2, varscan2
- REM2 | c.259G>C p.D87H | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99944660; called by muse, mutect2
- REM2 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.177); catalogued as rs376686140, COSV99944662; called by mutect2, varscan2
- RGL2 | c.449A>G p.D150G | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV101442499; called by muse, mutect2, varscan2
- RGS17 | c.145G>T p.G49W | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV99242878; called by muse, mutect2, varscan2
- RHCG | c.1298C>A p.A433E | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.92); PolyPhen benign (0.01); catalogued as COSV99174103; called by muse, mutect2, varscan2
- RHEBL1 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV99987999, COSV99988076; called by muse, mutect2
- RIBC1 | c.452C>G p.T151R | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.253); catalogued as COSV99394962; called by muse, mutect2, varscan2
- RIC3 | c.931G>A p.E311K (on ENST00000309737 / NM_001206671.4; = p.E310K on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/187 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as rs1186575924, COSV58301468; called by muse, mutect2, varscan2
- RIPOR3 | c.970G>C p.V324L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV99246465; called by muse, mutect2, varscan2
- RNF133 | c.209G>T p.R70I | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.65); catalogued as COSV100411611; called by muse, mutect2, varscan2
- ROS1 | c.4465G>T p.V1489F | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV63859762; called by muse, mutect2, varscan2
- RP1 | c.4297G>T p.A1433S | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as COSV55115067, COSV99607450; called by muse, mutect2, varscan2
- RSPO4 | c.408G>A p.Q136= | Splice Region (SNP) | VAF 6/38 reads (16%) | catalogued as COSV99449048; called by muse, mutect2, varscan2
- RUNX1T1 | c.902G>A p.R301H (on ENST00000265814 / NM_001198628.1; = p.R274H on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.869); catalogued as rs1248304190, COSV56147309; called by muse, mutect2, varscan2
- RXRA | c.199G>T p.V67F | Missense Mutation (SNP) | VAF 140/188 reads (74%) | SIFT tolerated (0.09); PolyPhen benign (0.208); catalogued as COSV100709256; called by muse, mutect2, varscan2
- RYR2 | c.4858C>A p.Q1620K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.164); catalogued as COSV100770068; called by muse, mutect2, varscan2
- RYR2 | c.8990C>G p.S2997C | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100770073, COSV63715197; called by muse, mutect2, varscan2
- S100A11 | c.162G>C p.Q54H | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV99643218, COSV99643243; called by muse, varscan2
- SCG3 | c.701C>A p.A234E | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.626); catalogued as COSV99590921; called by muse, mutect2, varscan2
- SCN11A | c.4360C>A p.H1454N | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100181540; called by muse, mutect2, varscan2
- SCN11A | c.978T>A p.Y326* | Nonsense Mutation (SNP) | VAF 46/67 reads (69%) | catalogued as COSV100181542; called by muse, mutect2, varscan2
- SCN3A | c.3950G>T p.R1317L | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51806154, COSV99326969; called by muse, mutect2, varscan2
- SCN8A | c.3592A>G p.N1198D | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.945); catalogued as COSV100633795; called by muse, mutect2, varscan2
- SCRN3 | c.850T>A p.S284T | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99767288; called by muse, mutect2, varscan2
- SEL1L | c.1594G>A p.G532S | Missense Mutation (SNP) | VAF 61/79 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100377880; called by muse, mutect2, varscan2
- SEMA5A | c.775G>T p.G259C | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101228191; called by muse, mutect2, varscan2
- SEPTIN4 | c.1241C>A p.P414H | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100400340; called by muse, varscan2
- SEPTIN4 | c.1240C>A p.P414T | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58729439; called by muse, varscan2
- SFMBT1 | c.1743G>T p.K581N | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99966094; called by muse, mutect2, varscan2
- SGCD | c.576G>T p.L192F (on ENST00000435422 / NM_001128209.2; = p.L193F on NM_000337.5) | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100549858; called by muse, varscan2
- SGCZ | c.721C>A p.H241N | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.056); catalogued as COSV101169655; called by muse, mutect2, varscan2
- SH3BGRL3 | c.131A>G p.N44S | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated (0.65); PolyPhen benign (0.03); catalogued as COSV99432234; called by muse, mutect2, varscan2
- SHANK2 | c.3457C>A p.P1153T | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as COSV99573927; called by muse, mutect2, varscan2
- SHROOM2 | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV101098575; called by muse, mutect2, varscan2
- SI | c.3350T>A p.V1117E | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV100015496; called by muse, mutect2, varscan2
- SI | c.2602C>A p.Q868K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100015498; called by muse, mutect2, varscan2
- SIGLEC14 | c.623del p.G208Afs*8 | Frame Shift Del (DEL) | VAF 28/78 reads (36%) | catalogued as COSV55779002; called by mutect2, varscan2
- SLC12A6 | c.1358C>A p.P453H (on ENST00000354181 / NM_001365088.1; = p.P402H on NM_005135.2) | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99271957; called by muse, mutect2, varscan2
- SLC16A7 | c.667A>G p.I223V | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.071); catalogued as COSV99676494; called by muse, mutect2, varscan2
- SLC26A9 | c.541G>C p.A181P | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100536359, COSV61601447, COSV61604671; called by muse, mutect2, varscan2
- SLC28A1 | c.72G>T p.M24I | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as rs1003901425, COSV99722961; called by muse, mutect2, varscan2
- SLC28A2 | c.1366C>T p.Q456* | Nonsense Mutation (SNP) | VAF 74/183 reads (40%) | catalogued as COSV100754716; called by muse, mutect2, varscan2
- SLC9B1 | c.240G>T p.M80I | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV56477629; called by muse, mutect2, varscan2
- SMYD5 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.8); PolyPhen benign (0.013); catalogued as COSV99242829; called by muse, mutect2, varscan2
- SNAPC4 | c.1084C>A p.Q362K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV100047195; called by muse, mutect2, varscan2
- SNRPB2 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV55719111, COSV99855861; called by muse, mutect2
- SP140L | c.660G>T p.W220C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99707182; called by muse, mutect2, varscan2
- SPATA17 | c.120A>T p.Q40H | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100861115; called by muse, mutect2, varscan2
- SPATA31D1 | c.3829T>A p.C1277S | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100782769; called by muse, mutect2, varscan2
- SPEF2 | c.952C>T p.Q318* | Nonsense Mutation (SNP) | VAF 50/99 reads (51%) | catalogued as COSV99213979, COSV99214194; called by muse, mutect2, varscan2
- SPRED2 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.251); catalogued as COSV100710214; called by muse, mutect2, varscan2
- SPTA1 | c.7134G>A p.Q2378= | Splice Region (SNP) | VAF 28/88 reads (32%) | catalogued as rs1429748317, CS046130, COSV100934908, COSV63748912; called by muse, mutect2, varscan2
- SPTA1 | c.2728G>C p.E910Q | Missense Mutation (SNP) | VAF 75/198 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100934909, COSV63755764; called by muse, mutect2, varscan2
- SPTAN1 | c.284A>T p.N95I | Missense Mutation (SNP) | VAF 58/68 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100823544; called by muse, mutect2, varscan2
- SPTB | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 134/152 reads (88%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.449); catalogued as rs747805892, COSV101072129; called by muse, mutect2, varscan2
- ST18 | c.3049A>C p.T1017P | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99389600; called by muse, mutect2, varscan2
- STAB2 | c.7156T>C p.F2386L | Missense Mutation (SNP) | VAF 65/120 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66343372; called by muse, mutect2, varscan2
- STEAP2 | c.754A>G p.I252V | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0.023); catalogued as rs745577344, COSV99840404; called by muse, mutect2, varscan2
- STEAP4 | c.991C>T p.L331F | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV100112570; called by muse, mutect2, varscan2
- SUPT6H | c.1485G>T p.E495D | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100112400; called by muse, mutect2, varscan2
- SYNE1 | c.13299C>A p.H4433Q (on ENST00000367255 / NM_182961.4; = p.H4362Q on NM_033071.3) | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.545); catalogued as COSV99563771; called by muse, mutect2, varscan2
- SYNJ2 | c.616G>T p.V206F | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.559); catalogued as COSV100840180, COSV62900536; called by muse, mutect2, varscan2
- SYT11 | c.191T>C p.I64T | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV100851312; called by muse, mutect2, varscan2
- TAAR2 | c.994G>A p.G332S (on ENST00000367931 / NM_001033080.1; = p.G287S on NM_014626.3) | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99255627, COSV99255636; called by muse, mutect2, varscan2
- TAF3 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1014233103, COSV100720129; called by muse, mutect2, varscan2
- TBC1D2 | c.116G>C p.R39P | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.692); catalogued as COSV100579899; called by muse, mutect2, varscan2
- TCN1 | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.099); catalogued as COSV57251899; called by muse, mutect2, varscan2
- TCTN2 | c.1791G>T p.Q597H | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV100315210; called by muse, mutect2, varscan2
- TDO2 | c.589C>A p.Q197K | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV101539743; called by muse, mutect2, varscan2
- TELO2 | c.1744G>T p.A582S | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99248319; called by muse, mutect2, varscan2
- TENM2 | c.5407A>G p.I1803V (on ENST00000518659 / NM_001122679.2; = p.I1564V on NM_001080428.3) | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101318651; called by muse, mutect2, varscan2
- TEX13A | c.1046C>A p.P349H | Missense Mutation (SNP) | VAF 49/77 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as COSV100781264; called by muse, mutect2, varscan2
- TEX2 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 110/298 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.34); catalogued as COSV99367097; called by muse, mutect2, varscan2
- TGFB1 | c.358A>G p.I120V | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs1195900235, COSV99700168; called by muse, mutect2, varscan2
- TINAG | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs115438249, COSV52508165; called by muse, mutect2, varscan2
- TINAG | c.1057C>A p.P353T | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99449567; called by muse, mutect2, varscan2
- TLR4 | c.1726C>A p.L576I (on ENST00000355622 / NM_138554.5; = p.L536I on NM_003266.4) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.885); catalogued as COSV100842760; called by muse, mutect2, varscan2
- TLR7 | c.2036A>G p.N679S | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV101027871; called by muse, mutect2, varscan2
- TMC4 | c.1321C>G p.L441V (on ENST00000617472 / NM_001145303.3; = p.L435V on NM_144686.4) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV99713861; called by muse, mutect2, varscan2
- TMEM125 | c.425G>T p.R142L | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0.196); catalogued as COSV101443200; called by muse, mutect2, varscan2
- TNIP3 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 20/34 reads (59%) | catalogued as COSV50254932, COSV99284473; called by muse, mutect2, varscan2
- TNIP3 | c.450G>T p.K150N | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV50247547, COSV99284475; called by muse, mutect2, varscan2
- TNRC6A | c.1034G>C p.W345S | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100169989; called by muse, mutect2, varscan2
- TOP2A | c.1481G>T p.R494L | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV101396189, COSV101396198; called by muse, mutect2, varscan2
- TPPP | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100862807; called by muse, mutect2, varscan2
- TRIM36 | c.1153T>C p.F385L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.222); catalogued as COSV99142396; called by muse, mutect2, varscan2
- TRIOBP | c.2701A>T p.N901Y | Missense Mutation (SNP) | VAF 107/275 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV100730850; called by muse, mutect2, varscan2
- TRMT61B | c.1223A>G p.K408R | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.009); catalogued as COSV100066585; called by muse, mutect2, varscan2
- TRPC5 | c.1630A>T p.T544S | Missense Mutation (SNP) | VAF 61/104 reads (59%) | SIFT tolerated (0.29); PolyPhen benign (0.145); catalogued as COSV99460869; called by muse, mutect2, varscan2
- TSHZ1 | c.244A>T p.S82C (on ENST00000580243 / NM_001308210.2; = p.S37C on NM_005786.6) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100433648; called by muse, mutect2, varscan2
- TTBK2 | c.426C>G p.I142M | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51159499, COSV99141534; called by muse, mutect2, varscan2
- TTC27 | c.355C>G p.Q119E | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100513027, COSV58655505; called by muse, mutect2, varscan2
- TTN | c.95420G>C p.R31807P (on ENST00000591111; = p.R24383P on NM_003319.4) | Missense Mutation (SNP) | VAF 26/90 reads (29%) | PolyPhen possibly damaging (0.861); catalogued as COSV100611955; called by muse, mutect2, varscan2
- TTN | c.88624G>A p.E29542K (on ENST00000591111; = p.E22118K on NM_003319.4) | Missense Mutation (SNP) | VAF 97/187 reads (52%) | PolyPhen possibly damaging (0.84); catalogued as COSV100611958; called by muse, mutect2, varscan2
- TTN | c.62848C>G p.L20950V (on ENST00000591111; = p.L13526V on NM_003319.4) | Missense Mutation (SNP) | VAF 58/128 reads (45%) | PolyPhen benign (0.021); catalogued as COSV100611960; called by muse, mutect2, varscan2
- TTN | c.14764A>G p.T4922A (on ENST00000591111; = p.T3995A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/176 reads (28%) | PolyPhen benign (0.406); catalogued as COSV100611962; called by muse, mutect2, varscan2
- TUBGCP6 | c.1480G>T p.A494S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0.06); catalogued as COSV50556862, COSV99030467; called by muse, varscan2
- UCHL5 | c.66T>G p.I22M | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); catalogued as COSV100814626; called by muse, varscan2
- ULBP1 | c.577T>C p.W193R | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99998158; called by muse, varscan2
- UNC13C | c.510G>T p.E170D | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.77); catalogued as COSV99517054; called by muse, mutect2, varscan2
- UPP2 | c.172G>C p.D58H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99134907; called by muse, mutect2, varscan2
- URGCP | c.1282G>T p.V428L (on ENST00000453200 / NM_001077663.3; = p.V419L on NM_017920.4) | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV99787312; called by muse, mutect2, varscan2
- USH2A | c.5080C>A p.Q1694K | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.628); catalogued as COSV100234490; called by muse, mutect2, varscan2
- USP32 | c.4297A>T p.N1433Y | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV100341990; called by muse, mutect2, varscan2
- VCX | c.504C>G p.S168R | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100406278; called by muse, mutect2, varscan2
- VEPH1 | c.979C>A p.L327I | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV100747558; called by muse, mutect2, varscan2
- WDPCP | c.2179G>T p.G727C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99705262; called by muse, mutect2, varscan2
- XKR6 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV58656363; called by muse, mutect2
- ZBED8 | c.1291G>T p.E431* | Nonsense Mutation (SNP) | VAF 38/58 reads (66%) | catalogued as COSV68825194; called by muse, mutect2, varscan2
- ZFHX4 | c.8394del p.D2799Ifs*35 | Frame Shift Del (DEL) | VAF 21/46 reads (46%) | catalogued as COSV51469819; called by mutect2, pindel, varscan2
- ZNF200 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.518); catalogued as COSV101205259; called by muse, mutect2, varscan2
- ZNF300 | c.947A>G p.Q316R | Missense Mutation (SNP) | VAF 75/120 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0.399); catalogued as rs576694189, COSV99199876; called by muse, mutect2, varscan2
- ZNF32 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.024); catalogued as COSV100986493; called by muse, mutect2, varscan2
- ZNF341 | c.2113C>T p.H705Y (on ENST00000375200 / NM_001282935.1; = p.H698Y on NM_032819.4) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); catalogued as rs764465178, COSV100677852; called by muse, mutect2, varscan2
- ZNF408 | c.1288G>C p.V430L | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0.193); catalogued as COSV100305476; called by muse, mutect2, varscan2
- ZNF415 | c.860T>C p.L287P | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54703912, COSV99701576; called by muse, mutect2, varscan2
- ZNF425 | c.2033G>A p.R678K | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs947397589, COSV100955471; called by muse, mutect2, varscan2
- ZNF528 | c.1802G>T p.G601V | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100846657, COSV64621183; called by muse, mutect2, varscan2
- ZNF568 | c.512C>A p.S171* | Nonsense Mutation (SNP) | VAF 8/109 reads (7%) | catalogued as COSV100451277; called by muse, mutect2
- ZNF649 | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 103/311 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV100031024; called by muse, mutect2, varscan2
- ZNF74 | c.1427A>C p.E476A | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV100677481; called by muse, mutect2, varscan2
- ZNF878 | c.1453G>C p.G485R | Missense Mutation (SNP) | VAF 51/66 reads (77%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as COSV101521193; called by muse, mutect2, varscan2
- CNST | c.495_496dup p.P166Rfs*32 | Frame Shift Ins (INS) | VAF 117/346 reads (34%) | called by mutect2, pindel, varscan2
- DCX | c.108_109delinsG p.S36Rfs*11 | Frame Shift Del (DEL) | VAF 57/144 reads (40%) | called by pindel, varscan2*
- DPY19L3 | c.1362del p.G455Afs*5 | Frame Shift Del (DEL) | VAF 43/115 reads (37%) | called by mutect2, pindel, varscan2
- EFS | c.1630_1631del p.E544Tfs*14 | Frame Shift Del (DEL) | VAF 20/129 reads (16%) | called by mutect2, pindel, varscan2
- FAT1 | c.1866_1867del p.V623Ifs*52 | Frame Shift Del (DEL) | VAF 26/49 reads (53%) | called by pindel, varscan2
- GPRC6A | c.307del p.C103Vfs*12 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | called by mutect2, pindel, varscan2
- IGKV1D-42 | c.17C>A p.P6H | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- IGKV2D-24 | c.271G>T p.G91W | Missense Mutation (SNP) | VAF 111/279 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIR2DL1 | c.935A>T p.Q312L | Missense Mutation (SNP) | VAF 173/477 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- KLHL4 | c.1901_1907del p.S634Ffs*21 | Frame Shift Del (DEL) | VAF 21/39 reads (54%) | called by mutect2, pindel, varscan2
- KRTAP10-9 | c.531del p.C178Afs*203 | Frame Shift Del (DEL) | VAF 80/339 reads (24%) | called by mutect2, pindel, varscan2
- MRGPRX3 | c.115del p.V40Sfs*3 | Frame Shift Del (DEL) | VAF 67/236 reads (28%) | called by mutect2, pindel, varscan2
- MYH4 | c.4528del p.Q1510Nfs*7 | Frame Shift Del (DEL) | VAF 37/132 reads (28%) | called by mutect2, pindel, varscan2
- NET1 | c.1506del p.F503Sfs*45 (on ENST00000355029 / NM_001047160.3; = p.F449Sfs*45 on NM_005863.5) | Frame Shift Del (DEL) | VAF 38/69 reads (55%) | called by mutect2, pindel, varscan2
- RAB22A | c.417_420del p.I140Mfs*5 | Frame Shift Del (DEL) | VAF 15/39 reads (38%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.1753C>A p.L585M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by mutect2, varscan2
- TFDP2 | c.759_761delinsAA p.R254Kfs*15 (on ENST00000489671 / NM_001178139.2; = p.R194Kfs*15 on NM_006286.5) | Frame Shift Del (DEL) | VAF 36/138 reads (26%) | called by pindel, varscan2*
- TRAJ37 | c.61C>A p.P21T | Missense Mutation (SNP) | VAF 21/25 reads (84%) | called by muse, mutect2
- TTC3 | c.1132_1150del p.S378Lfs*27 | Frame Shift Del (DEL) | VAF 7/48 reads (15%) | called by mutect2, pindel
- ACACB | c.5367C>A p.I1789= | Silent (SNP) | VAF 42/76 reads (55%) | catalogued as COSV100622868, COSV58131655; called by muse, mutect2, varscan2
- ADAMTS2 | c.495C>T p.A165= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV99202116; called by muse, mutect2, varscan2
- ADAMTS20 | c.5391T>C p.A1797= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV101239291; called by muse, mutect2, varscan2
- ADAMTS20 | c.1650G>A p.T550= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs964358021, COSV101239558, COSV67134264; called by muse, mutect2, varscan2
- ADGRG4 | c.3753C>A p.T1251= | Silent (SNP) | VAF 17/150 reads (11%) | catalogued as COSV99795434; called by muse, mutect2, varscan2
- ADGRG4 | c.5385T>G p.T1795= | Silent (SNP) | VAF 35/156 reads (22%) | catalogued as COSV99795436; called by muse, mutect2, varscan2
- AFF3 | c.366C>T p.P122= | Silent (SNP) | VAF 46/113 reads (41%) | catalogued as COSV100418821; called by muse, mutect2, varscan2
- AGAP3 | c.159G>T p.L53= (on ENST00000622464; = p.L89= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV52545170, COSV99880301; called by muse, mutect2, varscan2
- AHNAK | c.4896A>G p.P1632= | Silent (SNP) | VAF 101/243 reads (42%) | catalogued as COSV99947399; called by muse, mutect2, varscan2
- ALDH8A1 | c.1449C>A p.I483= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs778173764, COSV55642626; called by muse, mutect2, varscan2
- AP2A1 | c.1920C>T p.I640= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV100756266; called by muse, varscan2
- ATP10B | c.3318C>T p.Y1106= | Silent (SNP) | VAF 22/33 reads (67%) | catalogued as COSV100514930; called by muse, mutect2, varscan2
- ATP13A3 | c.2919G>A p.L973= | Silent (SNP) | VAF 14/127 reads (11%) | catalogued as COSV99756998; called by muse, mutect2, varscan2
- ATP6V0D2 | c.267C>A p.S89= | Silent (SNP) | VAF 28/166 reads (17%) | catalogued as COSV53417885, COSV99571687; called by muse, mutect2, varscan2
- ATXN2 | c.2925C>T p.S975= (on ENST00000550104; = p.S815= on NM_002973.4) | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as rs1166113582, COSV101112750; called by muse, mutect2, varscan2
- BCL2L14 | c.55C>T p.L19= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as COSV99845066; called by muse, mutect2, varscan2
- BMPER | c.426G>A p.G142= | Silent (SNP) | VAF 50/134 reads (37%) | catalogued as rs749814966, COSV99779585; called by muse, mutect2, varscan2
- C1QTNF4 | c.741G>A p.L247= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100209296; called by muse, mutect2, varscan2
- CACNA1E | c.1971G>A p.E657= | Silent (SNP) | VAF 58/186 reads (31%) | catalogued as COSV100702581; called by muse, mutect2, varscan2
- CACNG7 | c.324C>A p.L108= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV99712020; called by muse, mutect2, varscan2
- CAMK1G | c.585C>A p.P195= | Silent (SNP) | VAF 59/159 reads (37%) | catalogued as COSV99151688; called by muse, mutect2, varscan2
- CCDC190 | c.846C>T p.S282= | Silent (SNP) | VAF 58/142 reads (41%) | catalogued as COSV100905828; called by muse, mutect2, varscan2
- CCDC22 | c.657C>T p.G219= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100879793; called by muse, mutect2, varscan2
- CCL28 | c.207C>A p.R69= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV100742051; called by muse, mutect2
- CDC37 | c.705G>T p.R235= | Silent (SNP) | VAF 85/108 reads (79%) | catalogued as COSV99705782; called by muse, mutect2, varscan2
- CDH22 | c.1056C>A p.P352= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as COSV100952848; called by muse, mutect2, varscan2
- CDH6 | c.2100C>A p.P700= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV99419136, COSV99420904; called by muse, mutect2, varscan2
- CDH7 | c.1911C>A p.P637= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs1244474779, COSV100542345; called by muse, mutect2, varscan2
- CEACAM5 | c.1695C>T p.D565= | Silent (SNP) | VAF 102/231 reads (44%) | catalogued as rs782644830, COSV55751523; called by muse, mutect2, varscan2
- CEP350 | c.4026G>T p.S1342= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs772909339, COSV100854665; called by muse, varscan2
- CHRDL2 | c.1200T>C p.A400= (on ENST00000376332 / NM_001304415.1; = p.W419R on NM_015424.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 42/115 reads (37%) | catalogued as COSV99733779; called by muse, mutect2, varscan2
- CPT1C | c.612C>A p.V204= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV99773449; called by muse, mutect2, varscan2
- CSMD2 | c.3414G>A p.L1138= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs1252219187, COSV53965473; called by muse, mutect2, varscan2
- CTSG | c.297A>G p.Q99= | Silent (SNP) | VAF 106/136 reads (78%) | catalogued as COSV99361517; called by muse, mutect2, varscan2
- CYP27A1 | c.576G>T p.L192= | Silent (SNP) | VAF 12/226 reads (5%) | catalogued as COSV99298499; called by muse, mutect2
- DACT1 | c.1521A>G p.K507= | Silent (SNP) | VAF 182/214 reads (85%) | catalogued as COSV100241847; called by muse, mutect2, varscan2
- DDB1 | c.594A>T p.R198= | Silent (SNP) | VAF 108/279 reads (39%) | catalogued as rs777170888, COSV100074599; called by muse, mutect2, varscan2
- DDX56 | c.1212C>T p.L404= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV99345992, COSV99346072; called by muse, mutect2, varscan2
- DLGAP2 | c.1101G>A p.K367= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV101421879; called by muse, mutect2, varscan2
- DUSP29 | c.246G>A p.T82= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV100633317; called by muse, mutect2, varscan2
- DZIP1L | c.360C>T p.G120= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV59523694; called by muse, mutect2, varscan2
- EP400 | c.4941G>T p.A1647= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100200740, COSV57767015; called by muse, mutect2, varscan2
- ESPL1 | c.5397G>T p.L1799= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV99229287; called by muse, mutect2, varscan2
- EXOC1 | c.1188G>A p.K396= | Silent (SNP) | VAF 51/86 reads (59%) | catalogued as COSV100637861; called by muse, mutect2, varscan2
- FARP1 | c.2463G>T p.V821= | Silent (SNP) | VAF 180/256 reads (70%) | catalogued as COSV100130646; called by muse, varscan2
- FRG1 | c.495A>T p.I165= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as COSV99903083; called by muse, varscan2
- FRMPD4 | c.348G>A p.P116= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as rs763718836, COSV101042844; called by muse, mutect2, varscan2
- GABRA5 | c.402C>T p.F134= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs372061541; called by muse, mutect2
- GAPDH | c.621C>A p.I207= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV99975505; called by muse, mutect2, varscan2
- GFRA1 | c.474G>A p.A158= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs1466992042, COSV100815715; called by muse, mutect2
- GFRA3 | c.711C>A p.P237= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as COSV99218378; called by muse, mutect2, varscan2
- GIMAP8 | c.513G>A p.K171= | Silent (SNP) | VAF 9/179 reads (5%) | catalogued as COSV100217529, COSV56231278; called by muse, mutect2
- GNAL | c.693C>T p.I231= (on ENST00000269162 / NM_001142339.3; = p.I308= on NM_182978.4) | Silent (SNP) | VAF 12/279 reads (4%) | catalogued as COSV99303505; called by muse, mutect2
- GPKOW | c.253C>A p.R85= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV50242779, COSV99332637; called by muse, mutect2, varscan2
- GPKOW | c.252C>A p.A84= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV50245278, COSV99332640; called by muse, mutect2, varscan2
- GRIA1 | c.1206A>T p.S402= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs368699188; called by muse, mutect2, varscan2
- GRIN2A | c.1857C>A p.V619= | Silent (SNP) | VAF 35/106 reads (33%) | catalogued as COSV100409757; called by muse, mutect2, varscan2
- HCLS1 | c.921G>T p.G307= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV100100656; called by muse, mutect2
- IGKV1-5 | c.291C>A p.I97= | Silent (SNP) | VAF 61/206 reads (30%) | catalogued as rs541284837; called by muse, mutect2, varscan2
- IGKV1-9 | c.15C>A p.V5= | Silent (SNP) | VAF 42/173 reads (24%) | catalogued as rs536535238; called by muse, mutect2, varscan2
- IGKV2-30 | c.279C>A p.G93= | Silent (SNP) | VAF 69/246 reads (28%) | called by muse, mutect2, varscan2
- IGKV3-11 | c.213A>G p.A71= | Silent (SNP) | VAF 27/126 reads (21%) | catalogued as rs763407576; called by muse, mutect2, varscan2
- IL1RL1 | c.1482G>A p.E494= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV99294051; called by mutect2, varscan2
- IMMP1L | c.16C>T p.L6= | Silent (SNP) | VAF 7/98 reads (7%) | catalogued as COSV99540945; called by muse, mutect2
- IQSEC2 | c.2682C>T p.D894= (on ENST00000642864 / NM_001111125.3; = p.D689= on NM_015075.2) | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV100944898; called by muse, mutect2, varscan2
- IREB2 | c.618A>G p.Q206= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV99359382; called by muse, mutect2, varscan2
- IREB2 | c.906A>G p.E302= | Silent (SNP) | VAF 58/195 reads (30%) | catalogued as COSV99359383; called by muse, mutect2, varscan2
- JARID2 | c.624G>T p.S208= | Silent (SNP) | VAF 46/111 reads (41%) | catalogued as COSV100521866, COSV100521949; called by muse, mutect2, varscan2
- KCNJ12 | c.78G>C p.S26= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs571676444, COSV100054821, COSV100056109; called by mutect2, varscan2
- KIF1A | c.4398G>A p.L1466= (on ENST00000320389 / NM_001379639.1; = p.L1458= on NM_004321.8 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as COSV100240904; called by muse, mutect2
- KLHL4 | c.2052G>A p.L684= | Silent (SNP) | VAF 28/47 reads (60%) | catalogued as COSV100909553; called by muse, mutect2, varscan2
- LILRB4 | c.816C>A p.L272= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs768035893, COSV54404503, COSV99553453; called by muse, mutect2, varscan2
- LOXL3 | c.1176A>T p.T392= | Silent (SNP) | VAF 43/92 reads (47%) | catalogued as COSV99239665; called by muse, mutect2, varscan2
- LRP5 | c.2664C>T p.F888= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as rs373351312; called by muse, mutect2, varscan2
- MAGEB4 | c.582C>A p.T194= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs1193369755, COSV100974963; called by muse, mutect2, varscan2
- MAP2K3 | c.495C>A p.I165= (on ENST00000342679 / NM_145109.3; = p.I136= on NM_002756.4) | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV100383895; called by muse, mutect2, varscan2
- MAPKBP1 | c.4515C>T p.A1505= (on ENST00000456763 / NM_001128608.2; = p.A1499= on NM_014994.3) | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs1040048514, COSV99529404; called by muse, mutect2, varscan2
- MASP1 | c.1548C>A p.I516= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100537237; called by muse, mutect2
- MMP12 | c.879C>G p.T293= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV100404907, COSV100404950; called by muse, mutect2, varscan2
- MMP16 | c.990C>T p.T330= | Silent (SNP) | VAF 79/140 reads (56%) | catalogued as rs1450279866, COSV99688135; called by muse, mutect2, varscan2
- MOXD1 | c.120C>A p.G40= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV100914296; called by muse, mutect2, varscan2
- MRGPRE | c.168C>T p.N56= | Silent (SNP) | VAF 45/115 reads (39%) | catalogued as rs749454603, COSV101100016; called by muse, mutect2, varscan2
- MTRR | c.1854A>G p.K618= (on ENST00000264668; = p.K591= on NM_002454.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs760394620, COSV99241694; called by muse, mutect2, varscan2
- MUC4 | c.15450C>T p.A5150= (on ENST00000463781 / NM_018406.7; = p.A914= on NM_004532.6) | Silent (SNP) | VAF 90/312 reads (29%) | catalogued as COSV100204651; called by muse, mutect2, varscan2
- MYH4 | c.813A>G p.L271= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as COSV55124664; called by muse, mutect2, varscan2
- NAV3 | c.1515G>A p.L505= | Silent (SNP) | VAF 36/66 reads (55%) | catalogued as COSV99890777; called by muse, mutect2, varscan2
- NLGN4X | c.1521C>A p.L507= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV99321693; called by muse, mutect2, varscan2
- NLRP8 | c.2832G>T p.L944= | Silent (SNP) | VAF 40/95 reads (42%) | catalogued as COSV99405270; called by muse, mutect2, varscan2
- NOL11 | c.747G>A p.L249= | Silent (SNP) | VAF 36/79 reads (46%) | catalogued as COSV99475064; called by muse, mutect2, varscan2
- NOX5 | c.2136C>T p.R712= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV99533847; called by muse, mutect2, varscan2
- NR0B1 | c.282G>A p.P94= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV66763741, COSV66764402; called by muse, mutect2, varscan2
- NR2F1 | c.678G>C p.L226= | Silent (SNP) | VAF 44/75 reads (59%) | catalogued as COSV59068659; called by muse, mutect2, varscan2
- NSUN2 | c.1275A>T p.A425= | Silent (SNP) | VAF 42/86 reads (49%) | catalogued as COSV99243157; called by muse, mutect2, varscan2
- NSUN5 | c.864G>T p.A288= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs368355769, COSV53094078, COSV99392381; called by muse, mutect2, varscan2
- NUP62 | c.930G>T p.V310= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as COSV100352039, COSV61313208; called by muse, mutect2, varscan2
- NUTM1 | c.240C>T p.L80= | Silent (SNP) | VAF 30/159 reads (19%) | catalogued as rs1338066435, COSV100412240; called by muse, mutect2, varscan2
- OPCML | c.717G>A p.K239= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as COSV100101173, COSV59438384; called by muse, mutect2, varscan2
- OR10A4 | c.768C>A p.A256= | Silent (SNP) | VAF 55/129 reads (43%) | catalogued as COSV101139513; called by muse, mutect2, varscan2
- OR10K1 | c.93C>T p.F31= | Silent (SNP) | VAF 41/108 reads (38%) | catalogued as COSV99193541; called by muse, mutect2, varscan2
- OR2F1 | c.534C>T p.S178= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as COSV101231309; called by muse, mutect2, varscan2
- OR2L3 | c.366C>T p.Y122= | Silent (SNP) | VAF 101/248 reads (41%) | catalogued as COSV100741967; called by muse, mutect2, varscan2
- OR2T10 | c.513C>T p.S171= | Silent (SNP) | VAF 56/157 reads (36%) | catalogued as rs756378465, COSV100393698; called by muse, mutect2, varscan2
- OR2T4 | c.447C>T p.T149= | Silent (SNP) | VAF 50/190 reads (26%) | catalogued as rs879198197; called by mutect2, varscan2
- OR4S1 | c.141C>A p.I47= | Silent (SNP) | VAF 70/162 reads (43%) | catalogued as COSV100180246, COSV60680413; called by muse, mutect2, varscan2
- OR52D1 | c.627C>A p.A209= | Silent (SNP) | VAF 97/280 reads (35%) | catalogued as COSV100495221; called by muse, mutect2, varscan2
- OR52K2 | c.219G>T p.L73= | Silent (SNP) | VAF 81/200 reads (41%) | catalogued as COSV100355731; called by muse, mutect2, varscan2
- PALB2 | c.597T>G p.L199= | Silent (SNP) | VAF 100/251 reads (40%) | catalogued as COSV99848511; called by muse, mutect2, varscan2
- PARP3 | c.1548C>T p.L516= | Silent (SNP) | VAF 43/60 reads (72%) | catalogued as rs1559749357, COSV101290665; called by muse, mutect2, varscan2
- PAX1 | c.309C>T p.N103= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as rs760859962, COSV101270297; called by muse, mutect2, varscan2
- PCDHA12 | c.2202G>T p.P734= | Silent (SNP) | VAF 14/16 reads (88%) | catalogued as COSV56488495, COSV99166277; called by muse, mutect2, varscan2
- PCDHA4 | c.1791G>A p.V597= | Silent (SNP) | VAF 47/69 reads (68%) | catalogued as COSV100793426; called by muse, mutect2, varscan2
- PCDHA6 | c.1944G>T p.L648= | Silent (SNP) | VAF 37/54 reads (69%) | catalogued as rs1554132480, COSV100971475; called by muse, mutect2, varscan2
- PCDHGA2 | c.2073G>T p.L691= | Silent (SNP) | VAF 95/158 reads (60%) | catalogued as COSV99528199; called by muse, mutect2, varscan2
- PCDHGB6 | c.1497G>T p.L499= | Silent (SNP) | VAF 18/25 reads (72%) | catalogued as COSV54011782; called by muse, mutect2, varscan2
- PCLO | c.5640A>T p.V1880= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV100432471; called by muse, mutect2, varscan2
- PIGR | c.1860G>T p.G620= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as COSV100732510; called by muse, mutect2, varscan2
- PKDREJ | c.1353C>G p.L451= | Silent (SNP) | VAF 45/90 reads (50%) | catalogued as COSV99478861; called by muse, mutect2, varscan2
- PLA2G4E | c.2163C>T p.L721= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV101268566; called by muse, mutect2
- PORCN | c.333G>A p.E111= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV100400426; called by muse, mutect2, varscan2
- PPFIA2 | c.208C>A p.R70= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100332936, COSV100333353; called by muse, mutect2, varscan2
- PROM2 | c.2019C>A p.V673= | Silent (SNP) | VAF 39/88 reads (44%) | catalogued as COSV100468975; called by muse, mutect2, varscan2
- PRSS8 | c.549G>A p.L183= | Silent (SNP) | VAF 41/84 reads (49%) | catalogued as COSV99571437; called by muse, mutect2, varscan2
- PSMB2 | c.588C>T p.F196= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as rs373435113; called by muse, mutect2, varscan2
- PXN | c.1149C>A p.V383= (on ENST00000228307 / NM_001080855.3; = p.V349= on NM_002859.4) | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99935883; called by muse, mutect2, varscan2
- R3HDM1 | c.2463A>G p.G821= | Silent (SNP) | VAF 43/120 reads (36%) | catalogued as COSV99926189; called by muse, mutect2, varscan2
- RAB19 | c.513C>T p.V171= | Silent (SNP) | VAF 34/133 reads (26%) | catalogued as COSV99325095; called by muse, mutect2, varscan2
- RAB39B | c.171C>G p.R57= | Silent (SNP) | VAF 37/61 reads (61%) | catalogued as COSV101034974; called by muse, mutect2, varscan2
- RIMBP2 | c.1386G>T p.P462= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV55475092, COSV99899462; called by muse, mutect2, varscan2
- RIPK2 | c.450G>A p.Q150= | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as COSV99609870; called by muse, mutect2
- RNF133 | c.516C>T p.L172= | Silent (SNP) | VAF 56/164 reads (34%) | catalogued as COSV100411608; called by muse, mutect2, varscan2
- RPL8 | c.192G>T p.R64= | Silent (SNP) | VAF 38/231 reads (16%) | catalogued as COSV99369863; called by muse, mutect2, varscan2
- RUNX1T1 | c.258C>T p.A86= (on ENST00000265814 / NM_001198628.1; = p.A59= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV99751956; called by muse, mutect2, varscan2
- RYR2 | c.7956G>T p.L2652= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV100770071; called by muse, mutect2, varscan2
- SEPTIN4 | c.1239G>A p.L413= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as COSV100400341; called by muse, varscan2
- SERPING1 | c.1230C>A p.L410= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as COSV99557972; called by muse, mutect2, varscan2
- SGCZ | c.720C>A p.L240= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV101169656, COSV66013182; called by muse, mutect2, varscan2
- SIGLEC9 | c.1383C>A p.I461= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV99142572; called by muse, mutect2, varscan2
- SLC35A2 | c.627C>T p.S209= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV99504260; called by muse, mutect2, varscan2
- SLFN13 | c.1935C>T p.I645= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV99539988; called by muse, mutect2, varscan2
- TAF1L | c.2406C>T p.G802= | Silent (SNP) | VAF 56/181 reads (31%) | catalogued as rs1215590694, COSV99644683; called by muse, mutect2, varscan2
- TARS1 | c.1314G>A p.G438= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as COSV99465936; called by muse, mutect2, varscan2
- TAS2R4 | c.228G>A p.R76= | Silent (SNP) | VAF 67/187 reads (36%) | catalogued as COSV99924664; called by muse, mutect2, varscan2
- TBX10 | c.1005G>C p.P335= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100039730, COSV56876628; called by muse, mutect2, varscan2
- TFEB | c.948C>A p.I316= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as rs1318934593, COSV100026190, COSV100026372; called by muse, mutect2, varscan2
- TMEM44 | c.555G>T p.L185= | Silent (SNP) | VAF 31/50 reads (62%) | catalogued as COSV99861812; called by muse, mutect2, varscan2
- TRHDE | c.1644G>A p.R548= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV99670771; called by muse, mutect2, varscan2
- TRIM51 | c.1194G>T p.V398= | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as COSV99792586; called by muse, mutect2, varscan2
- TRIM67 | c.1314C>T p.T438= | Silent (SNP) | VAF 18/200 reads (9%) | catalogued as rs370010177; called by muse, mutect2
- TTN | c.66573C>A p.T22191= (on ENST00000591111; = p.T14767= on NM_003319.4) | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as COSV100611959, COSV60275596; called by muse, mutect2, varscan2
- USP2 | c.1140T>A p.P380= | Silent (SNP) | VAF 44/59 reads (75%) | catalogued as COSV99489654; called by muse, mutect2, varscan2
- UTP25 | c.552A>G p.K184= | Silent (SNP) | VAF 47/140 reads (34%) | catalogued as COSV101530953; called by muse, mutect2, varscan2
- VNN2 | c.651T>C p.Y217= | Silent (SNP) | VAF 43/144 reads (30%) | catalogued as rs763385186, COSV100426776; called by muse, mutect2, varscan2
- WIZ | c.4287G>T p.P1429= (on ENST00000673675 / NM_001371589.1; = p.P334= on NM_021241.3) | Silent (SNP) | VAF 79/104 reads (76%) | catalogued as COSV99653197; called by muse, mutect2, varscan2
- ZBTB4 | c.1884G>T p.L628= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV100263280; called by muse, mutect2, varscan2
- ZNF157 | c.1494T>G p.R498= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as COSV100998497, COSV65658821; called by muse, mutect2, varscan2
- ZNF346 | c.774C>T p.V258= | Silent (SNP) | VAF 67/118 reads (57%) | catalogued as COSV56157592; called by muse, mutect2, varscan2
- ZNF479 | c.84G>A p.E28= | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as COSV100482740, COSV58635959; called by muse, mutect2, varscan2
- ZNF592 | c.414C>T p.F138= | Silent (SNP) | VAF 45/191 reads (24%) | catalogued as rs1252416932, COSV55439543; called by muse, mutect2, varscan2
- ZP1 | c.424C>A p.R142= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as COSV99612414; called by muse, mutect2, varscan2
- AC073310.1 | n.375C>T | RNA (SNP) | VAF 80/197 reads (41%) | catalogued as rs371902318; called by muse, mutect2, varscan2
- AC244258.1 | n.915C>T | RNA (SNP) | VAF 63/209 reads (30%) | called by muse, mutect2, varscan2
- AL163540.1 | n.159G>A | RNA (SNP) | VAF 62/88 reads (70%) | called by muse, mutect2, varscan2
- ANKRD13D | c.*1158G>T | 3'UTR (SNP) | VAF 17/49 reads (35%) | catalogued as COSV100354559; called by muse, mutect2, varscan2
- CDKL1 | c.171+5366G>A | Intron (SNP) | VAF 22/59 reads (37%) | catalogued as COSV99367458; called by muse, mutect2, varscan2
- DCX | c.-22-418T>C | Intron (SNP) | VAF 113/179 reads (63%) | catalogued as COSV100576432; called by muse, mutect2, varscan2
- DLC1 | c.1348+90637C>G | Intron (SNP) | VAF 61/231 reads (26%) | catalogued as rs748790870, COSV99363083; called by muse, mutect2, varscan2
- DMD | c.31+83133C>T | Intron (SNP) | VAF 5/25 reads (20%) | catalogued as COSV99922317; called by muse, mutect2
- DST | c.4297-2189C>T | Intron (SNP) | VAF 28/133 reads (21%) | catalogued as COSV99755728; called by muse, mutect2, varscan2
- ELK1 | chrX:47650503 C>T | 5'Flank (SNP) | VAF 12/29 reads (41%) | catalogued as rs1328457488, COSV55953492, COSV99902085; called by muse, mutect2, varscan2
- LOXL2 | c.-83-17519A>C | Intron (SNP) | VAF 37/135 reads (27%) | catalogued as COSV100652641; called by muse, mutect2, varscan2
- OR2U1P | n.774T>A | RNA (SNP) | VAF 31/50 reads (62%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.2936T>C | RNA (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-51546C>A | Intron (SNP) | VAF 11/31 reads (35%) | catalogued as rs758196707, COSV101043796, COSV67442715; called by muse, mutect2
- SNORD116-12 | n.74C>A | RNA (SNP) | VAF 26/109 reads (24%) | catalogued as rs1186384686; called by muse, mutect2, varscan2
- TLR6 | c.*2A>T | 3'UTR (SNP) | VAF 6/13 reads (46%) | catalogued as COSV101126270; called by muse, mutect2, varscan2
- TRIM8 | c.*387C>T | 3'UTR (SNP) | VAF 38/62 reads (61%) | catalogued as rs866417960, COSV100193233; called by muse, mutect2, varscan2
- TTN | c.10361-4169C>A | Intron (SNP) | VAF 105/216 reads (49%) | catalogued as COSV100611963; called by muse, mutect2, varscan2
